Surgical pathology report (de-identified scan), TCGA case TCGA-DZ-6132, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DZ-6132-01A (Primary Tumor).

[REDACTED] Surgical Pathology
[REDACTED] Addendum/Procedure included)

REVISED REPORT

TISSUE DESCRIPTION:

Tissue from right lateral kidney (3.5 x 3.4 x 1.6 cm) and right kidney (2 specimens measuring 1.2 x 0.5 x 0.3 cm and 1.2 x 0.7 x 0.3 cm)

DIAGNOSIS:

Kidney, right, partial nephrectomy: Grade 2 (of 4) renal cell carcinoma, papillary cell type, forming a 2 x 1.8 x 1.8 cm mass.

The tumor is confined to the kidney. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are very focally positive.

Source: NCI Genomic Data Commons file 83182399-1ecc-4a28-8882-64cb290b72c8 (TCGA-DZ-6132.2E661B7A-927A-4FA8-BFA7-884AEA167BC1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).